Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040030-09A.3 (aliquot TARGET-15-SJMPAL040030-09A.3-01D) from TARGET case TARGET-15-SJMPAL040030, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,931 days).
Specimen TARGET-15-SJMPAL040030-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dbe454c-e336-4920-a3bf-f5d78a843e45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040030-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040030-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67350229-b7b8-4291-a88f-00e12769d33f

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, RNA 1, Silent 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/265 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKT3 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV55615418; called by muse, mutect2
- HMCN2 | c.13760C>T p.S4587L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs1315283512, COSV56739966; called by muse, mutect2, varscan2
- HSBP1L1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs757201263, COSV54099598; called by muse, mutect2, varscan2
- AL592490.1 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- C2orf78 | c.1181A>T p.D394V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP2 | c.3101A>G p.D1034G | Missense Mutation (SNP) | VAF 136/243 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPS15L1 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- FBN3 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); called by muse, mutect2
- GOT1L1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- LRP1 | c.7315C>T p.R2439W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MRPL46 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RAPGEF2 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2
- YIPF4 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- RREB1 | c.3747C>A p.P1249= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- TPRXL | n.904_918del | RNA (DEL) | VAF 4/39 reads (10%) | catalogued as rs1213217353; called by mutect2, pindel
